Somatic mutation profile of tumor specimen TCGA-NK-A7XE-01A (aliquot TCGA-NK-A7XE-01A-12D-A401-08) from TCGA case TCGA-NK-A7XE, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 66.6 years (24,319 days).
Specimen TCGA-NK-A7XE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8abf4802-2c03-4c5f-beed-a63582a69f8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NK-A7XE-10A (Blood Derived Normal), aliquot TCGA-NK-A7XE-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178c46b8-c19d-4f46-9ff7-ba6f3503096f

The open-access MAF lists 110 somatic variants for this specimen: 84 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Nonsense Mutation 4, In Frame Del 2, Intron 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.7024C>T p.R2342* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs886043113, CM021077, COSV99800122; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 50/149 reads (34%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4493C>G p.S1498C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54439532, COSV99720313; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4627C>T p.P1543S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as COSV99720314; called by muse, mutect2, varscan2
- ADCY3 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs1199007245, COSV53174311, COSV99568879; called by muse, mutect2, varscan2
- AFF4 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.163); catalogued as COSV99535219; called by muse, mutect2, varscan2
- AHNAK | c.9889G>C p.E3297Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99948745; called by muse, mutect2, varscan2
- ASCC3 | c.3419G>A p.R1140K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100226113; called by muse, mutect2
- BRD2 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100875777; called by muse, mutect2, varscan2
- C12orf56 | c.288T>A p.D96E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV100399694; called by muse, mutect2, varscan2
- CAPN11 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101291922; called by muse, mutect2, varscan2
- CARD6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV99621072; called by muse, mutect2, varscan2
- CBFA2T2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100656460; called by muse, mutect2, varscan2
- CDC42BPB | c.4931C>G p.S1644* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100775552; called by muse, mutect2, varscan2
- CDCA2 | c.2414A>C p.K805T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100399023; called by muse, mutect2, varscan2
- CDK12 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV70999897; called by muse, mutect2, varscan2
- CENPJ | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV101121555; called by muse, mutect2, varscan2
- COL12A1 | c.5771G>C p.R1924P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100486301, COSV59395186; called by muse, mutect2, varscan2
- CUBN | c.8642C>A p.T2881N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100913205; called by muse, mutect2, varscan2
- DDX4 | c.1579A>G p.K527E | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100737679; called by muse, mutect2, varscan2
- DENND4A | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.104); catalogued as COSV101475401; called by muse, mutect2, varscan2
- DZIP3 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100847956; called by muse, mutect2, varscan2
- ELMO3 | c.1280_1282del p.F427del (on ENST00000652269; = p.F374del on NM_024712.5) | In Frame Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs749868273; called by mutect2, pindel, varscan2
- FLG | c.4439C>G p.S1480* | Nonsense Mutation (SNP) | VAF 61/328 reads (19%) | catalogued as COSV100911902; called by muse, mutect2, varscan2
- FREM2 | c.4594A>G p.K1532E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV99749938; called by muse, mutect2, varscan2
- GIN1 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101204372; called by muse, mutect2, varscan2
- GLI1 | c.624+2T>A p.X208_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99954429; called by muse, mutect2, varscan2
- HASPIN | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs757736172, COSV53997639; called by muse, mutect2, varscan2
- HERC1 | c.4988G>C p.R1663T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV71247117, COSV71250813; called by muse, mutect2, varscan2
- INVS | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317976; called by muse, mutect2, varscan2
- JCAD | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948511; called by muse, mutect2, varscan2
- KANSL1L | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as COSV99910795; called by muse, mutect2, varscan2
- KDM7A | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs763990482, COSV50090140; called by muse, mutect2, varscan2
- KHDC4 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100850837; called by muse, varscan2
- KIAA1755 | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99642417; called by muse, mutect2
- KIAA1755 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99642419; called by muse, mutect2
- KLHL15 | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV100044359; called by muse, mutect2, varscan2
- KLK4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.481); catalogued as COSV100133678; called by muse, varscan2
- KRT36 | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100057670, COSV60204310; called by muse, mutect2, varscan2
- LRRC36 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs762633681, COSV99338963; called by muse, mutect2, varscan2
- LRRC4C | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.337); catalogued as COSV53435904; called by muse, mutect2, varscan2
- MGAT4B | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99482315; called by muse, mutect2, varscan2
- MUC17 | c.2825G>C p.R942T | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60301044; called by muse, mutect2, varscan2
- MYO6 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV64120103; called by muse, mutect2
- NFYB | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99527235; called by muse, mutect2, varscan2
- NYAP2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV99797843; called by muse, mutect2, varscan2
- OR4C3 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.017); catalogued as COSV100168117; called by muse, mutect2, varscan2
- OTOL1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100020148; called by muse, mutect2, varscan2
- PCDHA2 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100974077; called by muse, mutect2, varscan2
- PCDHGB3 | c.2375A>G p.D792G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99543207; called by muse, mutect2, varscan2
- PLXNA4 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1365101809, COSV100326021; called by muse, mutect2, varscan2
- POMK | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100505932; called by muse, mutect2, varscan2
- PTCH1 | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as rs753833857, COSV100109448; called by muse, mutect2, varscan2
- PTPRC | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100722904; called by muse, mutect2, varscan2
- RASA3 | c.2224A>T p.S742C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100481000; called by muse, mutect2, varscan2
- RNF43 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV101348496; called by muse, mutect2
- RPL19 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV99841530; called by muse, mutect2, varscan2
- RSPH10B | c.1646C>G p.S549C | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs775460368, COSV100521181, COSV100521370; called by muse, mutect2, varscan2
- SIGLEC1 | c.670C>G p.H224D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV99169849; called by muse, mutect2, varscan2
- SIX3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99578070; called by muse, mutect2
- SLC9B1 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99599932, COSV99600199; called by muse, mutect2, varscan2
- SLC9C2 | c.2437G>T p.A813S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.197); catalogued as COSV100876921; called by muse, mutect2, varscan2
- SLFN12 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100513171, COSV59226851; called by muse, mutect2, varscan2
- SMYD4 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100563156; called by muse, mutect2, varscan2
- SPTAN1 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV63989010; called by muse, mutect2, varscan2
- STPG4 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99681381; called by muse, mutect2, varscan2
- SVIL | c.4994G>A p.R1665K (on ENST00000355867 / NM_021738.3; = p.R1239K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100881437; called by muse, mutect2, varscan2
- SVIL | c.4804G>A p.E1602K (on ENST00000355867 / NM_021738.3; = p.E1176K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100881438; called by muse, mutect2
- TDRD5 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99676788; called by muse, mutect2, varscan2
- TEX14 | c.1563G>C p.Q521H (on ENST00000240361 / NM_001201457.2; = p.Q515H on NM_031272.5) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53619170, COSV53623896; called by muse, mutect2, varscan2
- TEX15 | c.5404G>T p.D1802Y (on ENST00000256246; = p.D2185Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754802025, COSV56341671, COSV56345448; called by muse, mutect2, varscan2
- TGM5 | c.1498C>T p.R500* (on ENST00000220420 / NM_201631.4; = p.R418* on NM_004245.4) | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs144532387, CM152139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769058292, COSV70262329; called by muse, mutect2, varscan2
- TNKS | c.2233G>A p.V745M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100127597; called by muse, mutect2, varscan2
- TRPC4AP | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as rs769441830, COSV99328737; called by muse, mutect2, varscan2
- TYW1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100658951; called by muse, mutect2, varscan2
- UNC13C | c.6052A>G p.T2018A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1205190785, COSV99515063; called by muse, mutect2, varscan2
- WNT1 | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99525334; called by muse, mutect2, varscan2
- YBEY | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99387273; called by muse, mutect2, varscan2
- ZBBX | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV100284646, COSV56800919; called by muse, mutect2, varscan2
- ZNF7 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs780700459, COSV100296029; called by muse, mutect2, varscan2
- ZNF773 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV99989452; called by muse, mutect2, varscan2
- HTR3C | c.435_437del p.S146del | In Frame Del (DEL) | VAF 23/107 reads (21%) | called by pindel, varscan2
- IGHE | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AHNAK | c.15477G>A p.L5159= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99947773, COSV99948743; called by muse, mutect2, varscan2
- ASIC2 | c.1266G>A p.A422= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs759168920, COSV99858893; called by muse, mutect2, varscan2
- C5orf49 | c.327C>T p.P109= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs1431180276, COSV100603519; called by muse, mutect2, varscan2
- CBFA2T2 | c.87G>A p.A29= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs749757115, COSV60075029; called by muse, mutect2, varscan2
- CFAP74 | c.4077C>T p.A1359= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs556102638; called by muse, mutect2, varscan2
- CSTF2T | c.1213C>T p.L405= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as COSV58655953; called by muse, mutect2, varscan2
- DHX34 | c.1149C>G p.V383= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100169800; called by muse, mutect2, varscan2
- DLG5 | c.4146C>T p.I1382= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs568757709, COSV64947676; called by muse, mutect2, varscan2
- EFNB3 | c.159G>A p.Q53= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99872880; called by muse, mutect2, varscan2
- FAM227B | c.1173T>C p.S391= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100175416; called by muse, mutect2, varscan2
- FAM78A | c.423C>A p.T141= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs760131990, COSV99908582; called by muse, mutect2, varscan2
- GLI3 | c.3669C>T p.Y1223= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs773687251, COSV67891236; ClinVar: likely benign; called by muse, mutect2, varscan2
- GON4L | c.2445G>A p.L815= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV99675240; called by muse, mutect2, varscan2
- LILRB3 | c.441G>A p.Q147= | Silent (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- MCC | c.2130C>T p.L710= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100203036; called by muse, mutect2, varscan2
- MGAT4B | c.1074G>A p.R358= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99482307; called by muse, mutect2, varscan2
- OR8K1 | c.919C>T p.L307= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99687455; called by muse, mutect2, varscan2
- PRKG1 | c.1395C>G p.L465= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100907396; called by muse, mutect2, varscan2
- RMC1 | c.1449G>C p.L483= | Silent (SNP) | VAF 638/683 reads (93%) | catalogued as COSV99340332; called by muse, mutect2, varscan2
- SLC24A3 | c.1764C>T p.L588= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV100042345; called by muse, mutect2, varscan2
- SVIL | c.5367G>A p.V1789= (on ENST00000355867 / NM_021738.3; = p.V1363= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100881436; called by muse, mutect2, varscan2
- TTLL7 | c.2223G>A p.V741= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99552601, COSV99552832; called by muse, mutect2, varscan2
- XIRP2 | c.3867G>A p.L1289= (on ENST00000628543; = p.L1464= on NM_152381.6) | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV54737256; called by muse, mutect2, varscan2
- AP003393.1 | n.515-741G>C | Intron (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100405676; called by muse, mutect2, varscan2
- CACNB2 | c.214-827C>T | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99995712; called by muse, mutect2, varscan2
- CLLU1 | n.1065C>G | RNA (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101029224; called by muse, mutect2, varscan2
